Gene-level copy-number profile of tumor specimen TCGA-86-8669-01A from TCGA case TCGA-86-8669, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 64.2 years (23,443 days).
Specimen TCGA-86-8669-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.4bb00b63-0b98-499d-8117-427efa944c19.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-86-8669-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dc4c202d-9132-4552-a6e4-d0a56d9829c5

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 1; copy number 2: 7,975; copy number 3: 15,790; copy number 4: 22,085; copy number 5: 10,177; copy number 6: 1,704; copy number 7: 152; copy number 8: 725; copy number 9: 821; copy number 10: 10; copy number 11: 153; copy number 12: 182; copy number 13: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-86-8669-01A-11D-2389-01): tumor purity 0.57, ploidy 3.66, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:90,838,903–90,839,037, 1 gene: TMSB4XP8.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,161 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:56,917,084–106,060,524, 787 genes, copy number 9 (broad region; genes not listed).
- chr11:111,347,757–111,455,630, 3 genes, copy number 10 (within-gene range 2–10): MIR4491, POU2AF1, RNU2-60P.
- chr14:29,576,479–30,191,898, 1 gene, copy number 11 (within-gene range 8–11): PRKD1.
- chr14:29,811,916–38,987,383, 164 genes, copy number 11–13 (broad region; genes not listed).
- chr14:42,259,731–42,989,483, 7 genes, copy number 10: AL445074.1, AL442163.1, AL450442.1, AL442163.2, AL442163.3, YWHAQP1, AL163153.1.
- chr20:58,515,379–64,313,132, 199 genes, copy number 11–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
